Gene-level copy-number profile of tumor specimen C3N-01766-04 from CPTAC case C3N-01766, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G2; Age at diagnosis: 63.5 years (23,195 days).
Specimen C3N-01766-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 47e8dab5-87b6-466a-80cb-fdebf6f07cfc.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-01766-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,221 have no estimate.
https://portal.gdc.cancer.gov/files/208c8f77-f16a-4146-98b4-d9c38552fc70

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 1: 6; copy number 2: 53,114; copy number 3: 149; copy number 4: 5,117; copy number 5: 14.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:20,029,399–20,044,827, 2 genes: OR4K13, OR4U1P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 14 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:57,770,619–62,275,678, 14 genes, copy number 5: AC023141.4, AC023141.8, AC023141.5, AC023141.12, AC023141.2, AC023141.9, AC023141.11, AC023141.3, AC023141.1, AC023141.10, AC023141.6, AC023141.7, AC023141.13, AC128676.1.

Autosomal genes at a single copy (total copy number 1): 6. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
